Somatic mutation profile of tumor specimen TCGA-BG-A0M9-01A (aliquot TCGA-BG-A0M9-01A-21W-A10C-09) from TCGA case TCGA-BG-A0M9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 73.1 years (26,708 days).
Specimen TCGA-BG-A0M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 036a29b4-018c-45a0-9216-ee2a694a7cba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M9-10A (Blood Derived Normal), aliquot TCGA-BG-A0M9-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df063c96-2f1e-4df3-85fe-f3adbdce8004

The open-access MAF lists 64 somatic variants for this specimen: 53 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Nonsense Mutation 9, Silent 8, Frame Shift Ins 4, Frame Shift Del 2, Intron 1, In Frame Del 1, Splice Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 56/500 reads (11%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 103/288 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 50/147 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); catalogued as COSV55918383, COSV55932743, COSV55991103; called by muse, mutect2, varscan2
- PIK3R1 | c.1380_1394del p.S460_D464del (on ENST00000521381 / NM_181523.3; = p.S190_D194del on NM_181504.4) | In Frame Del (DEL) | VAF 32/117 reads (27%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 206/482 reads (43%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 135/312 reads (43%) | catalogued as rs1060500122, CM110149, COSV64288740, COSV64297241; ClinVar: pathogenic; called by muse, varscan2
- ARID1A | c.3391C>T p.Q1131* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV61376561, COSV61380004; called by muse, mutect2, varscan2
- ASIC4 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1343350219, COSV61731653; called by muse, mutect2, varscan2
- BRIP1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 136/310 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs375246789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC150 | c.3282T>G p.Y1094* | Nonsense Mutation (SNP) | VAF 81/215 reads (38%) | catalogued as COSV55873901; called by muse, mutect2, varscan2
- CCT8L2 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs774406718, COSV63461984, COSV63463524; called by muse, mutect2, varscan2
- CKAP4 | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65172433; called by muse, mutect2, varscan2
- CLDN25 | c.39dup p.L14Afs*24 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs772015749; called by pindel, varscan2
- CRNN | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 319/741 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV55121736; called by muse, mutect2, varscan2
- CSMD1 | c.376T>G p.F126V | Missense Mutation (SNP) | VAF 100/183 reads (55%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV68198799; called by muse, mutect2, varscan2
- CTCF | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 53/146 reads (36%) | catalogued as COSV50466874; called by muse, mutect2, varscan2
- DHX35 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs149661086; called by muse, mutect2, varscan2
- DRC1 | c.2104A>T p.S702C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as rs769945578, COSV55501646, COSV55517188; called by muse, mutect2, varscan2
- EIF6 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs773641573, COSV55769719; called by muse, mutect2, varscan2
- EPHB4 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs758888214, COSV62267941, COSV62269321; called by muse, mutect2
- EXOC2 | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs755697381, COSV100034341, COSV57864357; called by muse, mutect2, varscan2
- FRY | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100969050, COSV66569363; called by muse, mutect2, varscan2
- GORAB | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV63027786; called by muse, mutect2, varscan2
- GTPBP1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 97/118 reads (82%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as rs761281921, COSV53284130; called by muse, mutect2, varscan2
- ING1 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV58168738, COSV58170541; called by muse, mutect2, varscan2
- ITGA8 | c.344-1G>T p.X115_splice | Splice Site (SNP) | VAF 110/236 reads (47%) | catalogued as COSV65228057; called by muse, mutect2, varscan2
- KIAA1217 | c.2212G>T p.D738Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56815882; called by muse, mutect2, varscan2
- LGI4 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59533393; called by muse, mutect2, varscan2
- LMAN1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 178/456 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as rs538087229, COSV51826692; called by muse, mutect2, varscan2
- MARK1 | c.1460C>G p.T487S | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV65067232; called by muse, mutect2, varscan2
- MCF2 | c.2282A>C p.D761A | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV58483690; called by muse, mutect2, varscan2
- MED14 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61356726; called by muse, mutect2
- PAK3 | c.834C>A p.D278E (on ENST00000262836 / NM_001324328.2; = p.D263E on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 196/494 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV53273678, COSV53276445; called by muse, varscan2
- PCDH19 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.841); catalogued as COSV55261885; called by muse, mutect2, varscan2
- PLA2G4A | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV66553594, COSV66554714; called by muse, mutect2, varscan2
- PLCXD1 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs749603595, COSV67541792; called by muse, mutect2, varscan2
- PRTG | c.2696A>G p.N899S | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs373042810; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3387dup p.A1130Sfs*9 | Frame Shift Ins (INS) | VAF 195/371 reads (53%) | catalogued as rs752866106; called by mutect2, varscan2
- RYR1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139006437, COSV62099806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN10A | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 55/114 reads (48%) | catalogued as rs1168396269, COSV71860734; called by muse, mutect2, varscan2
- SEC16B | c.957A>T p.E319D | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV57625170; called by muse, mutect2, varscan2
- SERPINB2 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs764303590, COSV53072863; called by muse, mutect2, varscan2
- SETDB2 | c.1126C>A p.Q376K | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51644286; called by muse, mutect2, varscan2
- SLC22A8 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.57); catalogued as rs202159634, COSV60324748; called by muse, mutect2, varscan2
- SSTR2 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59535128; called by muse, mutect2, varscan2
- TNRC6B | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 195/231 reads (84%) | catalogued as COSV57294459; called by muse, mutect2, varscan2
- TRPM3 | c.5063G>A p.R1688Q (on ENST00000357533 / NM_001366142.2; = p.R1543Q on NM_020952.6) | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as rs150876089; called by muse, mutect2, varscan2
- ZBTB4 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs1448917427, COSV60978973; called by muse, mutect2, varscan2
- ZCCHC8 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs370436302; called by muse, mutect2, varscan2
- ZSCAN5A | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs141546124; called by muse, mutect2
- DNAH8 | c.658_661dup p.A221Gfs*6 | Frame Shift Ins (INS) | VAF 172/420 reads (41%) | called by mutect2, pindel, varscan2
- MAST3 | c.301_305del p.S101Pfs*38 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- SLC4A10 | c.2375del p.F792Sfs*15 (on ENST00000446997 / NM_001354461.2; = p.F762Sfs*15 on NM_022058.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 112/453 reads (25%) | called by mutect2, pindel, varscan2
- BAG5 | c.1173C>G p.T391= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs200127933, COSV54570968; called by muse, mutect2, varscan2
- EFCAB6 | c.3579G>A p.T1193= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs771360780, COSV53061484; called by muse, mutect2, varscan2
- FNDC3B | c.973C>A p.R325= | Silent (SNP) | VAF 64/823 reads (8%) | catalogued as COSV61037308, COSV61041242; called by muse, mutect2
- H2AC11 | c.324C>T p.V108= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs779798489, COSV60362075; called by muse, mutect2, varscan2
- SHROOM4 | c.3642T>C p.D1214= | Silent (SNP) | VAF 76/184 reads (41%) | catalogued as COSV56788424, COSV56797979; called by muse, mutect2, varscan2
- SLC8A2 | c.1971C>T p.C657= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV52639426; called by muse, mutect2, varscan2
- TDRD1 | c.612C>T p.I204= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs755774670, COSV52587688; called by muse, mutect2, varscan2
- TNFRSF10C | c.363C>T p.S121= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs754666961, COSV63511589; called by muse, mutect2
- ITGA3 | c.*171G>A | 3'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as COSV50310190; called by muse, mutect2, varscan2
- MAGEA5 | n.80G>T | RNA (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+4677T>C | Intron (SNP) | VAF 105/233 reads (45%) | catalogued as rs1009686626, COSV53137155; called by muse, mutect2, varscan2
